Somatic mutation profile of tumor specimen TARGET-10-PATAXS-09A (aliquot TARGET-10-PATAXS-09A-01D) from TARGET case TARGET-10-PATAXS, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 1.0 years (367 days).
Specimen TARGET-10-PATAXS-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 880cfe28-2507-4b18-898d-8a57dc0d0ce9.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PATAXS-10A (Blood Derived Normal), aliquot TARGET-10-PATAXS-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/73cf2259-8086-4c26-807b-3c4951212879

The open-access MAF lists 17 somatic variants for this specimen: 15 protein-altering or splice-affecting, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 15, Intron 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EDN3 | c.286C>A p.R96S | Missense Mutation (SNP) | VAF 4/23 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM101978, COSV61109096; called by muse, mutect2
- IL31RA | c.903G>C p.W301C | Missense Mutation (SNP) | VAF 30/163 reads (18%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.719); catalogued as COSV51683214; called by muse, mutect2, varscan2
- MYO16 | c.5315C>T p.T1772I | Missense Mutation (SNP) | VAF 16/102 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.03); catalogued as COSV62754884; called by muse, mutect2, varscan2
- RASAL2 | c.215G>A p.R72H | Missense Mutation (SNP) | VAF 19/67 reads (28%) | SIFT deleterious (0.03); PolyPhen benign (0.226); catalogued as rs778302043, COSV62710006; called by muse, varscan2
- SMCR8 | c.440G>A p.R147H | Missense Mutation (SNP) | VAF 4/27 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58179250; called by muse, mutect2
- STRIP2 | c.1210C>A p.Q404K | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT tolerated (0.39); PolyPhen benign (0.049); catalogued as COSV50805896; called by mutect2, varscan2
- TMPRSS15 | c.1607C>T p.T536I | Missense Mutation (SNP) | VAF 10/158 reads (6%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as COSV53043597; called by muse, mutect2
- ADSS2 | c.142G>T p.D48Y | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- AOPEP | c.212C>A p.A71D | Missense Mutation (SNP) | VAF 6/66 reads (9%) | SIFT tolerated (0.44); PolyPhen benign (0); called by muse, mutect2
- CR1 | c.3724C>A p.P1242T | Missense Mutation (SNP) | VAF 6/52 reads (12%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.999); called by muse, varscan2
- DSCAML1 | c.4837G>T p.A1613S (on ENST00000321322; = p.A1553S on NM_020693.4) | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.652); called by muse, mutect2, varscan2
- FASTKD5 | c.444G>T p.L148F | Missense Mutation (SNP) | VAF 3/35 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- LRRD1 | c.475G>T p.D159Y | Missense Mutation (SNP) | VAF 3/39 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.817); called by muse, mutect2
- MANSC1 | c.866G>T p.R289L | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT tolerated (0.26); PolyPhen benign (0.045); called by muse, mutect2
- PHF21A | c.1481G>T p.C494F (on ENST00000418153 / NM_001101802.3; = p.C448F on NM_016621.5 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 3/38 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- LMF1 | c.514+2458G>T | Intron (SNP) | VAF 3/28 reads (11%) | called by muse, mutect2
- SYTL2 | c.1459+1793G>T | Intron (SNP) | VAF 4/36 reads (11%) | called by mutect2, varscan2
